Somatic mutation profile of tumor specimen TCGA-E8-A418-01A (aliquot TCGA-E8-A418-01A-11D-A23M-08) from TCGA case TCGA-E8-A418, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 75.9 years (27,737 days).
Specimen TCGA-E8-A418-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e677568-30c2-4dda-be5e-d51a5a68579a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E8-A418-10A (Blood Derived Normal), aliquot TCGA-E8-A418-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6af82405-e606-4e01-9e6f-46ee6ebb2749

The open-access MAF lists 35 somatic variants for this specimen: 31 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 29, Silent 4, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADH1B | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 78/205 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.211); catalogued as rs762807646, COSV59295747, COSV59297779; called by muse, mutect2, varscan2
- BICRAL | c.2363C>G p.S788C | Missense Mutation (SNP) | VAF 15/314 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV58407459; called by muse, mutect2
- CHD2 | c.5435C>T p.S1812L | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.057); catalogued as COSV67712218; called by muse, mutect2
- CPT1A | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs141658962, COSV99680722; called by muse, mutect2, varscan2
- DLEC1 | c.487G>C p.A163P | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV57303437; called by muse, mutect2, varscan2
- DNAJA2 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV57694826; called by muse, mutect2, varscan2
- DNMT1 | c.2116G>A p.D706N | Missense Mutation (SNP) | VAF 31/304 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.313); catalogued as rs1254979538, COSV61581713; called by muse, mutect2
- EVC | c.1349C>A p.A450E | Missense Mutation (SNP) | VAF 70/160 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.033); catalogued as COSV53835889; called by muse, mutect2, varscan2
- FAM122A | c.206A>G p.H69R | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV55253412; called by muse, mutect2, varscan2
- GAS2L3 | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV57158284; called by muse, mutect2
- HCN1 | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.007); catalogued as COSV57496411, COSV57526158; called by muse, mutect2, varscan2
- INTS10 | c.396G>T p.L132F | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67604669; called by muse, mutect2, varscan2
- KMT2A | c.10544C>T p.S3515F | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.485); catalogued as COSV63289550; called by muse, mutect2, varscan2
- MCHR1 | c.662C>A p.T221K | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.172); catalogued as COSV50762186; called by muse, mutect2, varscan2
- MSANTD4 | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.132); catalogued as rs1565386562, COSV57286474; called by muse, mutect2, varscan2
- MUC6 | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs1237974019, COSV70145637; called by muse, mutect2, varscan2
- PCSK1 | c.2192C>T p.T731I | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as COSV60736643; called by muse, mutect2
- PDHX | c.59T>G p.F20C | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.319); catalogued as COSV53507838; called by muse, mutect2, varscan2
- POGLUT1 | c.991A>G p.N331D | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV55157639; called by muse, mutect2, varscan2
- PPP6R3 | c.2197A>G p.K733E (on ENST00000393800 / NM_001352375.2; = p.K653E on NM_018312.5) | Missense Mutation (SNP) | VAF 76/189 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55732245; called by muse, mutect2, varscan2
- PTPRR | c.1562G>A p.S521N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs765515412, COSV51740425; called by muse, mutect2, varscan2
- RER1 | c.504C>T p.H168= | Splice Region (SNP) | VAF 52/156 reads (33%) | catalogued as COSV56580930; called by muse, mutect2, varscan2
- RTTN | c.6515A>G p.N2172S | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs969559210, COSV55348838; called by muse, mutect2, varscan2
- RYR1 | c.5335C>G p.P1779A | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.053); catalogued as COSV62104282; called by muse, mutect2, varscan2
- SLC13A1 | c.206T>A p.F69Y | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV52014577; called by muse, mutect2, varscan2
- ZNF337 | c.1214T>C p.V405A | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.038); catalogued as COSV53322455; called by muse, mutect2, varscan2
- IARS1 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2
- KMT2A | c.10543T>G p.S3515A | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PPM1D | c.1446_1450del p.T483Kfs*4 | Frame Shift Del (DEL) | VAF 40/109 reads (37%) | called by mutect2, pindel, varscan2
- CCN4 | c.444C>T p.D148= | Silent (SNP) | VAF 69/203 reads (34%) | catalogued as rs755626224, COSV51532431, COSV51535531; ClinVar: likely benign; called by muse, mutect2, varscan2
- NUTM1 | c.3111C>T p.L1037= | Silent (SNP) | VAF 52/126 reads (41%) | catalogued as COSV59218003; called by muse, mutect2, varscan2
- PADI1 | c.1284C>T p.G428= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV64938007; called by muse, mutect2, varscan2
- SPHK2 | c.1380T>C p.A460= | Silent (SNP) | VAF 97/235 reads (41%) | catalogued as COSV55339875; called by muse, mutect2, varscan2
